Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5683, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5683-01A (Primary Tumor).

DIAGNOSIS

(A) PERINEPHRIC FAT, PERMANENT:

Adipose tissue, no tumor present.

(B) RIGHT RENAL MASS, UPPER POLE, INKED AT MARGIN:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN
NUCLEAR GRADE 3 (5.5 CM).

Parenchymal margin, free of tumor.

(C) PERINEPHRIC FAT ADDITIONAL:

Fibroadipose tissue, no tumor present.

GROSS DESCRIPTION

(A) PERINEPHRIC FAT, PERMANENT- Two portions of adipose tissue (11.5 x
4.5 x 1.5 cm and 9.0 x 5.5 x 2.0 cm) are homogenous without lesion.

SECTION CODE: A1-A5, representative portion. [REDACTED]

(B) RIGHT RENAL MASS UPPER POLE, INK AT MARGIN - A partial nephrectomy
specimen (8.0 x 7.0 x 3.5 cm).

A solid well- circumscribed tumor (5.5 x 5.0 x 3.0 cm) is identified 2.0
mm from the purple inked parenchymal margin. It has a variegated
appearance with yellow and red hemorrhagic areas. The remainder of the
tumor is surrounded by adipose tissue.

A photograph is obtained. Portions are submitted for electron
microscopy.

INK CODE: The purple ink area is re-inked in black.

SECTION CODE: B1, mass with closest perpendicular renal
parenchymal margin for frozen section; B2-B5, tumor with perpendicular
renal parenchymal margin; B6-B9, tumor with adjacent adipose tissue.

[REDACTED]
*FS/DX: MARGIN, FREE OF TUMOR. [REDACTED]

(C) PERINEPHRIC FAT ADDITIONAL - A single portion of adipose tissue
(21.0 x 14.0 x 3.5 cm) has attached fascia without gross lesion.

SECTION CODE: C1-C6, representative portions of adipose tissue and
fascia [REDACTED]

CLINICAL HISTORY

History of right renal mass.

SNOMED CODES

T-71000, M-82123

Source: NCI Genomic Data Commons file 44c57a90-b5af-4f6a-bdf9-37f7eee85883 (TCGA-CJ-5683.3426104C-95A8-4BC0-A323-106F558AA306.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).